Somatic mutation profile of tumor specimen TCGA-NI-A4U2-01A (aliquot TCGA-NI-A4U2-01A-11D-A28X-10) from TCGA case TCGA-NI-A4U2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 71.2 years (26,011 days).
Specimen TCGA-NI-A4U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d64066d-ce02-4f9f-8d69-5f5a159951d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NI-A4U2-10A (Blood Derived Normal), aliquot TCGA-NI-A4U2-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efe9682a-c82d-4f66-9a6c-1b6dd02a155f

The open-access MAF lists 131 somatic variants for this specimen: 101 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 29, Nonsense Mutation 5, Frame Shift Del 5, Splice Site 5, In Frame Ins 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.14464T>A p.Y4822N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68945074; called by muse, mutect2, varscan2
- ABCA6 | c.4310A>G p.D1437G | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52637127; called by muse, mutect2, varscan2
- ADAM12 | c.1332+1G>T p.X444_splice | Splice Site (SNP) | VAF 42/85 reads (49%) | catalogued as COSV100900099; called by muse, mutect2, varscan2
- ADAM12 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.127); catalogued as COSV100900100; called by muse, mutect2, varscan2
- AKR1E2 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761782479, COSV53629953; called by muse, mutect2, varscan2
- AOAH | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV51738217; called by muse, mutect2, varscan2
- ARFIP1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV61883914, COSV61883968; called by muse, mutect2
- ARHGAP20 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV52809052; called by muse, mutect2, varscan2
- BCO2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV63062916; called by muse, mutect2, varscan2
- BCORL1 | c.3118C>G p.L1040V | Missense Mutation (SNP) | VAF 77/124 reads (62%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); catalogued as COSV54392997; called by muse, mutect2, varscan2
- BPIFA3 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64925715; called by muse, mutect2, varscan2
- C1QTNF2 | c.303G>A p.M101I (on ENST00000393975; = p.M56I on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV67432550; called by muse, mutect2, varscan2
- CACNA1E | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV62383135, COSV62387665; called by muse, mutect2, varscan2
- CACNA2D2 | c.1430G>A p.G477D | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.833); catalogued as COSV56562121, COSV99817263; called by muse, mutect2, varscan2
- CCBE1 | c.400+2T>A p.X134_splice | Splice Site (SNP) | VAF 8/176 reads (5%) | catalogued as COSV67949560; called by muse, mutect2
- CCDC174 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57980514; called by muse, mutect2, varscan2
- CHRNB2 | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63807934; called by muse, mutect2
- CLCN5 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56583117; called by muse, mutect2, varscan2
- CNTLN | c.2312T>C p.V771A | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.301); catalogued as COSV52072965; called by muse, mutect2, varscan2
- CPB2 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1398416151, COSV51673327; called by muse, mutect2, varscan2
- CTR9 | c.2956C>A p.P986T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV63728205; called by muse, mutect2, varscan2
- CTSK | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 55/127 reads (43%) | catalogued as COSV55011313; called by muse, mutect2, varscan2
- DCC | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV59144021; called by muse, varscan2
- DNMT1 | c.4129G>A p.V1377M | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV61577799; called by muse, mutect2, varscan2
- DVL2 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50035277, COSV99138667; called by muse, mutect2, varscan2
- ESYT1 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs773005777, COSV57272211; called by mutect2, varscan2
- FOXP4 | c.2029G>A p.E677K (on ENST00000307972 / NM_001012426.1; = p.E664K on NM_138457.3) | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV57219025; called by muse, mutect2, varscan2
- GAB3 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 92/125 reads (74%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); catalogued as COSV65819063; called by muse, mutect2, varscan2
- GNAI2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as COSV58028549; called by muse, mutect2, varscan2
- GRM7 | c.2123G>T p.S708I | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV63137038; called by muse, varscan2
- GTF3C1 | c.609-2A>T p.X203_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | catalogued as COSV62240013; called by muse, mutect2, varscan2
- HNF1A | c.730A>G p.R244G | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57460893; called by muse, mutect2, varscan2
- HNF1A | c.1059del p.T354Rfs*10 | Frame Shift Del (DEL) | VAF 28/153 reads (18%) | catalogued as COSV57460911; called by pindel, varscan2*
- HNRNPA3 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV66820727, COSV66820821; called by muse, mutect2, varscan2
- HYDIN | c.4320C>G p.I1440M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV66831223, COSV66832841; called by muse, mutect2, varscan2
- IGSF1 | c.3751G>A p.G1251R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV63836221, COSV63836821; called by muse, mutect2, varscan2
- IL12RB2 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV52022310; called by muse, mutect2, varscan2
- IPO7 | c.1544T>A p.V515E | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63352599; called by muse, mutect2, varscan2
- IRS2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101019144, COSV65478263; called by muse, varscan2
- KCNMB3 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58570253; called by muse, mutect2, varscan2
- KIAA0100 | c.4982G>T p.R1661L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as COSV66491568, COSV66497521; called by muse, mutect2, varscan2
- KIF25 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as COSV63027080; called by muse, varscan2
- KLHL1 | c.1930A>G p.T644A | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV64769566; called by muse, mutect2, varscan2
- LGSN | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65726641; called by muse, mutect2, varscan2
- LMO7 | c.4853G>A p.G1618D (on ENST00000357063; = p.G1299D on NM_005358.5) | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58532773; called by muse, mutect2, varscan2
- LRP12 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as COSV52627344; called by muse, varscan2
- LRP8 | c.1912G>C p.E638Q | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60097378; called by muse, mutect2, varscan2
- LRRIQ1 | c.3894G>T p.K1298N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs758320651, COSV101279615; called by muse, mutect2, varscan2
- LRRIQ1 | c.3895A>T p.R1299* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV67828258; called by muse, mutect2, varscan2
- LRRIQ1 | c.4721-1G>C p.X1574_splice | Splice Site (SNP) | VAF 20/47 reads (43%) | catalogued as rs1302045567, COSV67828268; called by muse, mutect2, varscan2
- MGAT3 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV57864746; called by muse, mutect2, varscan2
- MRPL53 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749014275, COSV50688446; called by muse, mutect2
- MST1 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56532925; called by muse, mutect2, varscan2
- MYO3B | c.2278A>T p.M760L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV58699394; called by muse, mutect2
- NANOG | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as rs771687755, COSV57551140; called by muse, mutect2, varscan2
- NCKAP5 | c.5225C>A p.P1742Q | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as COSV58436753; called by muse, mutect2, varscan2
- NDN | c.830A>G p.E277G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV59359173; called by muse, mutect2, varscan2
- NDUFV2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs890369537, COSV59187039; called by mutect2, varscan2
- NR1I2 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.178); catalogued as COSV61977880, COSV61979089; called by muse, mutect2, varscan2
- NUP98 | c.4506-1G>C p.X1502_splice (on ENST00000359171 / NM_001365126.1; = p.X1485_splice on NM_016320.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 36/102 reads (35%) | catalogued as COSV61430522; called by muse, mutect2, varscan2
- OR10H4 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.41); catalogued as COSV100437683; called by muse, mutect2
- OSBPL6 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs1452795375, COSV51914285; called by muse, mutect2, varscan2
- PDZRN3 | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373968116, COSV55195228; called by muse, mutect2, varscan2
- PEX13 | c.362A>C p.Q121P | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV54369579; called by muse, mutect2, varscan2
- PEX5L | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55842623; called by muse, mutect2, varscan2
- PGM3 | c.955A>C p.S319R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV52283313; called by muse, mutect2, varscan2
- PLA2G4C | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs1250422484, COSV62784732; called by muse, mutect2, varscan2
- PLP1 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002828, COSV58276060; called by muse, mutect2, varscan2
- PLXNA4 | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.404); catalogued as COSV58115431; called by muse, mutect2, varscan2
- PPIP5K2 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV58604411; called by muse, mutect2, varscan2
- PRPF40A | c.2577T>G p.H859Q | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV68356723; called by muse, varscan2
- RAB3IL1 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV100076464; called by muse, mutect2
- RUSC1 | c.1781G>C p.S594T (on ENST00000368352 / NM_001105203.2; = p.S125T on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.564); catalogued as COSV52738874; called by muse, mutect2, varscan2
- SAMD9L | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV59080610; called by muse, mutect2, varscan2
- SCN1B | c.61T>A p.C21S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52893842; called by muse, mutect2, varscan2
- SIGLEC10 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59480392; called by muse, mutect2, varscan2
- SLC25A5 | c.326T>G p.F109C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58625768; called by muse, varscan2
- SLC26A11 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs1304103622, COSV63279175; called by muse, mutect2, varscan2
- SLC3A2 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV58603151; called by muse, mutect2, varscan2
- SMC5 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as COSV63192339; called by muse, mutect2, varscan2
- TBC1D9 | c.3175C>T p.L1059F | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71307192; called by muse, mutect2, varscan2
- TENT5D | c.413G>A p.C138Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.136); catalogued as COSV57635882, COSV57638460; called by muse, mutect2, varscan2
- TGFBR1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66625271; called by muse, mutect2, varscan2
- TMBIM4 | c.704T>G p.V235G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53968420; called by muse, mutect2, varscan2
- TMPRSS7 | c.1592G>A p.R531K (on ENST00000452346; = p.R405K on NM_001042575.2) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69980241; called by muse, mutect2, varscan2
- TNFRSF8 | c.797A>C p.D266A | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV55795538; called by muse, mutect2, varscan2
- TOP2B | c.2097T>A p.H699Q (on ENST00000264331 / NM_001330700.2; = p.H694Q on NM_001068.3) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV51970296; called by muse, mutect2
- TRAF5 | c.1439A>G p.Q480R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759328690, COSV54821970; called by muse, mutect2, varscan2
- TRIM41 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59318272; called by muse, mutect2
- TTN | c.25400G>A p.W8467* (on ENST00000591111; = p.W7540* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV59876824; called by muse, mutect2
- YIF1B | c.803G>A p.R268Q (on ENST00000339413 / NM_001039673.3; = p.R253Q on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV56650099; called by muse, varscan2
- ZFHX3 | c.6598G>A p.E2200K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51713688; called by muse, mutect2, varscan2
- ZNF480 | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57995402; called by muse, mutect2, varscan2
- ZSWIM1 | c.652A>C p.S218R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.05); catalogued as COSV54846248; called by muse, mutect2, varscan2
- CNTROB | c.2187_2194del p.D730Afs*3 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | called by mutect2, pindel, varscan2
- HMGCR | c.1699_1700insCAAGAC p.N567delinsTRH | In Frame Ins (INS) | VAF 28/105 reads (27%) | called by mutect2, varscan2
- HMGCR | c.1701del p.N567Kfs*7 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | called by mutect2, pindel*, varscan2
- IL6ST | c.12_38del p.L4_L12del | In Frame Del (DEL) | VAF 27/229 reads (12%) | called by mutect2, pindel
- UNKL | c.1960_1976del p.G654Hfs*55 (on ENST00000389221 / NM_001372107.1; = p.G150Hfs*55 on NM_001276414.2) | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | called by mutect2, pindel, varscan2
- USP34 | c.8109_8117dup p.T2704_S2706dup | In Frame Ins (INS) | VAF 40/234 reads (17%) | called by mutect2, varscan2
- ZDHHC4 | c.303del p.L102Ffs*7 | Frame Shift Del (DEL) | VAF 56/174 reads (32%) | called by mutect2, pindel, varscan2
- AGPAT1 | c.409C>T p.L137= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV61247322; called by muse, mutect2, varscan2
- CILP2 | c.1008A>G p.R336= | Silent (SNP) | VAF 59/219 reads (27%) | catalogued as COSV52273676; called by muse, mutect2, varscan2
- EPB41L1 | c.741C>T p.T247= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV52435767; called by muse, mutect2, varscan2
- EPRS1 | c.1254A>G p.P418= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV65098149; called by muse, mutect2, varscan2
- FBXL3 | c.546T>A p.T182= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV62918568; called by muse, mutect2, varscan2
- FGD2 | c.411C>T p.R137= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as COSV51462882; called by muse, mutect2, varscan2
- FRMD3 | c.1263C>T p.A421= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV58458831; called by muse, mutect2
- FZR1 | c.9G>A p.Q3= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as COSV58050970; called by muse, mutect2, varscan2
- IBSP | c.576C>T p.S192= | Silent (SNP) | VAF 72/219 reads (33%) | catalogued as COSV56895165; called by muse, mutect2, varscan2
- KIAA0408 | c.1251G>A p.E417= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs774400628, COSV64105936; called by mutect2, varscan2
- LRP2 | c.8523G>A p.L2841= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV55547528; called by muse, mutect2, varscan2
- METTL21A | c.273T>A p.T91= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV55881379; called by muse, mutect2, varscan2
- MUC2 | c.582G>A p.K194= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2
- NRG1 | c.1593C>T p.Y531= (on ENST00000405005 / NM_013964.5; = p.Y536= on NM_013956.5) | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs576124928, COSV55153115; called by muse, mutect2, varscan2
- OR9K2 | c.576T>C p.S192= (on ENST00000305377; = p.S170= on NM_001005243.1) | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV59531612, COSV59532766; called by muse, mutect2, varscan2
- OTX1 | c.1044A>T p.S348= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV56994254; called by muse, mutect2, varscan2
- P2RY8 | c.105G>T p.A35= | Silent (SNP) | VAF 39/122 reads (32%) | catalogued as COSV101184038, COSV67177030; called by muse, mutect2, varscan2
- PRDM14 | c.426G>A p.P142= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV52571178, COSV99400433; called by muse, mutect2
- RYR1 | c.4044A>G p.K1348= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV62093543; called by muse, varscan2
- SHANK1 | c.3516C>T p.S1172= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53243055; called by muse, mutect2, varscan2
- SLC25A13 | c.360A>G p.T120= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV55705367; called by muse, varscan2
- SLC9A6 | c.1476A>G p.V492= | Silent (SNP) | VAF 49/83 reads (59%) | catalogued as rs891695661, COSV65787699; called by muse, mutect2, varscan2
- TLR1 | c.1107G>A p.G369= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV58303823; called by muse, mutect2, varscan2
- TRPM8 | c.2908C>T p.L970= | Silent (SNP) | VAF 81/198 reads (41%) | catalogued as COSV61221362; called by muse, mutect2, varscan2
- TTC33 | c.678A>T p.S226= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV61802398, COSV61802913; called by muse, mutect2, varscan2
- UNC13C | c.4017T>A p.S1339= | Silent (SNP) | VAF 73/245 reads (30%) | catalogued as COSV52857713; called by muse, mutect2, varscan2
- USP2 | c.1527G>A p.R509= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as COSV52728334; called by muse, mutect2, varscan2
- WDR43 | c.471A>G p.T157= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV56098251; called by muse, mutect2, varscan2
- ZNF558 | c.81C>T p.G27= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as rs762746194, COSV56862727; called by muse, mutect2, varscan2
- EIF4A2 | c.771+123A>G | Intron (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56216363; called by muse, mutect2, varscan2
